Somatic mutation profile of tumor specimen C3L-02809-04 (aliquot CPT0174700007) from CPTAC case C3L-02809, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.0 years (30,685 days).
Specimen C3L-02809-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7100203c-f94d-45fd-836b-45237ea3ef25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02809-31 (Blood Derived Normal), aliquot CPT0175500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af74eb72-b2d8-4c83-987e-dce70951b820

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 172/557 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 118/446 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs781206225, COSV53987558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOPEP | c.1730C>T p.P577L (on ENST00000375315 / NM_001193329.1; = p.P478L on NM_032823.5) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs143555020; called by muse, mutect2, varscan2
- CAND2 | c.2234G>A p.R745H (on ENST00000456430 / NM_001162499.2; = p.R652H on NM_012298.3) | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs755177838, COSV99929621, COSV99929636; called by muse, mutect2, varscan2
- CEP192 | c.6851C>T p.T2284I | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374861272; called by muse, mutect2, varscan2
- CFAP251 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 92/514 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); catalogued as rs1427374175; called by muse, mutect2, varscan2
- CNTN4 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 83/577 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as rs760085098, COSV61868851; called by muse, mutect2, varscan2
- DCAF4L2 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 74/830 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV60476327; called by muse, mutect2
- EDIL3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as rs752603385, COSV56901771; called by muse, mutect2, varscan2
- FSD1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 97/603 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs370463498; called by muse, mutect2, varscan2
- IGHG2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 174/769 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs375526803; called by muse, mutect2, varscan2
- LRRC43 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99928274; called by muse, mutect2, varscan2
- MCM8 | c.2356G>A p.V786I | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs768013365, COSV54511561; called by muse, mutect2, varscan2
- MGAT3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as rs747893252, COSV100361829; called by muse, mutect2, varscan2
- MSN | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs772017818; called by muse, mutect2, varscan2
- MUC16 | c.24513G>T p.Q8171H | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.047); catalogued as COSV101200259; called by muse, mutect2, varscan2
- MYH1 | c.4531C>T p.Q1511* | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as rs758051881, COSV56853315; called by muse, mutect2, varscan2
- NLRP4 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749461870, COSV56722459; called by muse, mutect2, varscan2
- OGT | c.2335A>G p.M779V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as rs1179616611, COSV65481612; called by muse, mutect2, varscan2
- PLCD4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs547899357; called by muse, mutect2, varscan2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2, varscan2
- THEG | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371760649; called by muse, mutect2, varscan2
- TTN | c.49721G>A p.R16574H (on ENST00000591111; = p.R9150H on NM_003319.4) | Missense Mutation (SNP) | VAF 23/218 reads (11%) | PolyPhen probably damaging (0.982); catalogued as rs183010574; called by muse, mutect2, varscan2
- ZNF469 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 73/430 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1367488672, COSV71258289, COSV71259251; called by muse, mutect2, varscan2
- AK8 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ANKRD34C | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C12orf29 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.024); called by muse, varscan2
- CCM2L | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF2 | c.313A>G p.N105D (on ENST00000416382 / NM_001025077.3; = p.N112D on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACT1 | c.125A>C p.Q42P | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR149 | c.1744dup p.I582Nfs*6 | Frame Shift Ins (INS) | VAF 22/227 reads (10%) | called by mutect2, pindel
- IFNA1 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRX2 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 56/638 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2
- ITGBL1 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KMT2D | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 143/480 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT77 | c.759-5G>A | Splice Region (SNP) | VAF 50/301 reads (17%) | called by muse, mutect2, varscan2
- MDGA2 | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- NOM1 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PCLO | c.429T>A p.D143E | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.361); called by muse, mutect2
- PDE8A | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- ROBO1 | c.3461A>T p.D1154V | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- STK11IP | c.2728_2740del p.S910Pfs*54 | Frame Shift Del (DEL) | VAF 81/483 reads (17%) | called by mutect2, pindel, varscan2
- ZNF710 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 139/567 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC138647.1 | c.336C>T p.P112= | Silent (SNP) | VAF 37/314 reads (12%) | catalogued as rs1237274245; called by muse, mutect2, varscan2
- ADCY10 | c.4116C>A p.I1372= | Silent (SNP) | VAF 181/695 reads (26%) | catalogued as COSV63240493; called by muse, mutect2, varscan2
- COL6A2 | c.2874C>T p.H958= | Silent (SNP) | VAF 82/368 reads (22%) | catalogued as rs765550338, COSV99385721; called by muse, mutect2, varscan2
- DIRAS3 | c.117C>T p.R39= | Silent (SNP) | VAF 62/501 reads (12%) | catalogued as rs1359297766, COSV63970826; called by muse, mutect2, varscan2
- FLG2 | c.2370G>A p.Q790= | Silent (SNP) | VAF 28/702 reads (4%) | catalogued as rs1354264489; called by muse, mutect2
- JPH3 | c.1476C>T p.P492= | Silent (SNP) | VAF 66/156 reads (42%) | catalogued as rs537678092; called by muse, mutect2, varscan2
- KCNJ12 | c.54C>T p.D18= | Silent (SNP) | VAF 38/671 reads (6%) | catalogued as rs781815544, COSV59163119; called by muse, mutect2
- MAGOH | c.226T>C p.L76= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as rs368006653; called by muse, mutect2
- PCDHB7 | c.2094C>G p.L698= | Silent (SNP) | VAF 112/1816 reads (6%) | called by muse, mutect2
- SHANK1 | c.1371G>A p.A457= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs1007850886; called by muse, mutect2, varscan2
- VHLL | c.21C>T p.N7= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs138677254; called by muse, mutect2, varscan2
- AEBP1 | c.1840+63C>T | Intron (SNP) | VAF 17/107 reads (16%) | catalogued as rs942116911; called by muse, mutect2, varscan2
- ITGA7 | c.3316-929G>T | Intron (SNP) | VAF 83/358 reads (23%) | called by muse, mutect2, varscan2
- OLA1 | c.-1+723_-1+727del | Intron (DEL) | VAF 65/358 reads (18%) | called by mutect2, pindel, varscan2
